CCDI case PBBNYL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/89f4d820-1532-4878-b546-01c8cfc2121c

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Epithelioid sarcoma: ICD-O-3 morphology code: 8804/3; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 15.3 years (5,582 days).

Biospecimens (3 samples)
- Sample 0DDTE3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDTE4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDTE5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
